Somatic mutation profile of tumor specimen MP2PRT-PAVEKE-TMP1-A (aliquot MP2PRT-PAVEKE-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVEKE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,100 days).
Specimen MP2PRT-PAVEKE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 242e022d-6112-45dd-8e6d-c3348b4229e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEKE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEKE-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfd7e595-38d6-408f-8154-e605012118b8

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH6 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as rs774976574, COSV54070709; called by muse, mutect2, varscan2
- EXTL1 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs760157945; called by muse, mutect2, varscan2
- HK3 | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 193/395 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762226493, COSV52844459; called by muse, mutect2, varscan2
- MAGEE1 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63909046; called by muse, mutect2, varscan2
- MUC2 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 10/281 reads (4%) | catalogued as rs766608809; called by muse, mutect2
- PRKN | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 140/314 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV58234698; called by muse, varscan2
- REPS1 | c.2345C>A p.S782Y (on ENST00000450536 / NM_001286611.2; = p.S781Y on NM_031922.4) | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57811159; called by muse, mutect2
- TTN | c.48023C>G p.A16008G (on ENST00000591111; = p.A8584G on NM_003319.4) | Missense Mutation (SNP) | VAF 130/284 reads (46%) | PolyPhen benign (0.132); catalogued as COSV100615949; called by muse, mutect2, varscan2
- FAM171B | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406841 TATTACTGTCTACAGGATTATACTACCCCATTCACAGTGTTACAA>CTGGGCTTTG | Missense Mutation (DEL) | VAF 82/215 reads (38%) | called by pindel, varscan2*
- PCDHGA4 | c.2273C>G p.A758G | Missense Mutation (SNP) | VAF 237/492 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1077G>A p.E359= | Silent (SNP) | VAF 27/492 reads (5%) | called by muse, mutect2
- MRPS5 | c.1095G>A p.K365= | Silent (SNP) | VAF 47/260 reads (18%) | called by muse, mutect2, varscan2
- PLXNA3 | c.3507C>G p.G1169= | Silent (SNP) | VAF 233/537 reads (43%) | catalogued as COSV100860346; called by muse, mutect2, varscan2
- VWF | c.4800G>A p.A1600= | Silent (SNP) | VAF 95/404 reads (24%) | catalogued as rs201264909, COSV54619678; ClinVar: likely benign; called by muse, mutect2, varscan2
